CPTAC case C3L-07111 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/780768e8-9147-4341-bf93-7a5f945cb33c

Demographics
Sex at birth: male; Race: white; Year of birth: 1962; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 58.8 years (21,488 days); Year of diagnosis: 2020; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,498 days (4.1 years); Days to last follow up: 1,498 days (4.1 years); Tumor focality: Multifocal.
   Pathology details: Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 5; Lymphatic invasion present: Yes; Margin status: Indeterminate; Vascular invasion present: Yes.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 252 days; Disease response: With Tumor.
- Days to follow up: 651 days (1.8 years); Disease response: With Tumor.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07111-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 395 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07111-24: Section location: Left axillar lymph node; Percent tumor nuclei: 80; Percent necrosis: 20.
- Sample C3L-07111-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 365 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-07111-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
